Somatic mutation profile of tumor specimen C3N-00314-03 (aliquot CPT0012070011) from CPTAC case C3N-00314, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 79.0 years (28,865 days).
Specimen C3N-00314-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c374981e-f0a0-4ca2-b938-125c35112e61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00314-31 (Blood Derived Normal), aliquot CPT0012150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb02fb13-4780-4377-a115-ea9f08a95f3f

The open-access MAF lists 97 somatic variants for this specimen: 65 protein-altering or splice-affecting, 21 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 21, Intron 9, Frame Shift Del 7, Nonsense Mutation 3, Splice Region 3, 5'UTR 1, Frame Shift Ins 1, In Frame Del 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.3712G>A p.G1238S | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as rs200733032; called by muse, mutect2, varscan2
- AKAP13 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs779331144, COSV63466066; called by muse, mutect2, varscan2
- AP3B1 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 49/508 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV54877011; called by muse, mutect2
- BEST1 | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 18/713 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as CM067981; called by muse, mutect2
- CARD10 | c.2486G>A p.R829Q | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.194); catalogued as rs769750011, COSV99325255; called by muse, mutect2, varscan2
- CSMD3 | c.4069C>G p.P1357A (on ENST00000297405 / NM_001363185.1; = p.P1253A on NM_052900.3) | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52108152; called by muse, mutect2, varscan2
- DISP1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.283); catalogued as rs908032421, COSV99450110; called by muse, mutect2, varscan2
- DNAH5 | c.13084G>T p.D4362Y | Missense Mutation (SNP) | VAF 61/434 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54234974; called by muse, mutect2, varscan2
- LILRA4 | c.96G>C p.W32C | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52494279; called by muse, mutect2, varscan2
- NCAN | c.3353G>A p.R1118H | Missense Mutation (SNP) | VAF 52/858 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs370172612; called by muse, mutect2
- NRDE2 | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 35/369 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as rs1566699491; called by muse, mutect2
- PDCL3 | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 56/562 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs748802211; called by muse, mutect2
- REG3G | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99709302; called by muse, mutect2, varscan2
- SYNJ2 | c.1777G>T p.A593S | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745840620; called by muse, mutect2, varscan2
- USH2A | c.3750G>C p.K1250N | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.085); catalogued as COSV100244169, COSV56403783; called by muse, mutect2
- ZNF207 | c.780+1G>T p.X260_splice | Splice Site (SNP) | VAF 30/340 reads (9%) | catalogued as COSV58301642; called by muse, mutect2
- ZNF419 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1397210318; called by muse, mutect2
- ABCC5 | c.1832A>G p.Q611R | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ACBD5 | c.794A>C p.E265A (on ENST00000375888 / NM_001352568.1; = p.E256A on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/323 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- AKAP11 | c.2480A>T p.E827V | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2
- AKIRIN2 | c.204del p.F69Sfs*17 | Frame Shift Del (DEL) | VAF 15/122 reads (12%) | called by mutect2, pindel, varscan2
- AL645922.1 | c.3771dup p.L1258Tfs*4 | Frame Shift Ins (INS) | VAF 24/223 reads (11%) | called by mutect2, pindel, varscan2
- ANKRD42 | c.1058C>G p.T353S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARHGAP32 | c.4746_4747del p.R1582Sfs*26 (on ENST00000310343 / NM_001378025.1; = p.R1233Sfs*26 on NM_014715.4) | Frame Shift Del (DEL) | VAF 24/218 reads (11%) | called by pindel, varscan2
- BMP5 | c.581C>A p.T194K | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC178 | c.1883A>C p.K628T | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.646); called by muse, mutect2
- CCDC9 | c.246del p.T83Pfs*85 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- CEACAM1 | c.1013C>A p.T338K | Missense Mutation (SNP) | VAF 65/445 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CES1 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 32/794 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- CHAT | c.1980G>T p.V660= | Splice Region (SNP) | VAF 28/390 reads (7%) | called by muse, mutect2
- CNTNAP2 | c.698_700del p.G233del | In Frame Del (DEL) | VAF 25/180 reads (14%) | called by mutect2, pindel, varscan2
- COL6A5 | c.4669G>T p.E1557* | Nonsense Mutation (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- CRYM | c.773C>A p.S258Y | Missense Mutation (SNP) | VAF 36/546 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DNMT1 | c.79C>A p.R27= | Splice Region (SNP) | VAF 38/357 reads (11%) | called by muse, mutect2, varscan2
- DPPA2 | c.329G>C p.S110T | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- DUXB | c.507G>C p.L169F | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- EIF4E | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ESPL1 | c.2668C>G p.L890V | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- FOXN1 | c.1573C>G p.L525V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- GASK1B | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 47/416 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- GEMIN5 | c.417del p.F139Lfs*11 | Frame Shift Del (DEL) | VAF 20/196 reads (10%) | called by mutect2, pindel, varscan2
- HRNR | c.776A>T p.Q259L | Missense Mutation (SNP) | VAF 101/893 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- IGSF10 | c.6162del p.D2055Ifs*4 | Frame Shift Del (DEL) | VAF 23/195 reads (12%) | called by mutect2, pindel, varscan2
- ITIH6 | c.3354del p.L1119Cfs*3 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- KCNG1 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- KLRG2 | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LIF | c.222C>G p.F74L | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- MECOM | c.1426G>T p.A476S (on ENST00000468789 / NM_001105078.4; = p.A664S on NM_004991.4) | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NUTM1 | c.1600del p.R534Efs*11 | Frame Shift Del (DEL) | VAF 13/124 reads (10%) | called by mutect2, varscan2
- PCNT | c.8040G>T p.E2680D | Missense Mutation (SNP) | VAF 51/388 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PIKFYVE | c.5074C>A p.Q1692K | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB3A | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 21/235 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.166); called by muse, mutect2
- RCC1 | c.808C>A p.H270N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.955); called by muse, mutect2
- SCO1 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 46/420 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- SDAD1 | c.196-5T>A | Splice Region (SNP) | VAF 24/164 reads (15%) | called by muse, mutect2, varscan2
- SERPINA12 | c.923T>A p.V308E | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2
- SLTM | c.1553C>T p.T518I | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- SMG1 | c.7465G>A p.D2489N | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SMYD4 | c.2188G>T p.E730* | Nonsense Mutation (SNP) | VAF 24/414 reads (6%) | called by muse, mutect2
- TOE1 | c.295T>A p.S99T | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TP53BP2 | c.2746A>G p.K916E (on ENST00000343537 / NM_001031685.3; = p.K787E on NM_005426.2) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- TSPY1 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 126/2008 reads (6%) | called by muse, mutect2
- ZBTB16 | c.1037T>G p.L346W | Missense Mutation (SNP) | VAF 60/467 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ZMYM4 | c.4279C>A p.P1427T | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- ZNF512B | c.1328T>C p.L443P | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AK3 | c.457C>T p.L153= | Silent (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- ANKRD30A | c.1650G>A p.P550= (on ENST00000611781; = p.P494= on NM_052997.2) | Silent (SNP) | VAF 15/164 reads (9%) | catalogued as rs538041220; called by muse, mutect2
- ATP5MC2 | c.216C>A p.A72= | Silent (SNP) | VAF 21/281 reads (7%) | catalogued as COSV100101072; called by muse, mutect2
- CACNA2D2 | c.924G>A p.K308= | Silent (SNP) | VAF 18/317 reads (6%) | called by muse, mutect2
- CAPN1 | c.315A>T p.T105= | Silent (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- DOK2 | c.1116G>T p.A372= | Silent (SNP) | VAF 18/140 reads (13%) | called by muse, mutect2, varscan2
- ESYT3 | c.309C>T p.G103= | Silent (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- HIP1 | c.309C>G p.L103= | Silent (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.231T>C p.H77= | Silent (SNP) | VAF 53/382 reads (14%) | catalogued as rs1170472411, COSV51533984; called by muse, mutect2, varscan2
- KCNG1 | c.1182G>C p.L394= | Silent (SNP) | VAF 22/205 reads (11%) | catalogued as COSV65369535; called by muse, mutect2
- KLK14 | c.318G>A p.R106= | Silent (SNP) | VAF 21/474 reads (4%) | catalogued as COSV50069329; called by muse, mutect2
- KMT2C | c.8979C>T p.L2993= | Silent (SNP) | VAF 28/320 reads (9%) | catalogued as COSV51439610; called by muse, mutect2
- NVL | c.234A>G p.L78= | Silent (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- PLXNA4 | c.4473C>T p.I1491= | Silent (SNP) | VAF 34/348 reads (10%) | called by muse, mutect2, varscan2
- PRSS27 | c.444C>T p.P148= | Silent (SNP) | VAF 18/161 reads (11%) | catalogued as rs915952005; called by muse, mutect2, varscan2
- RBMXL3 | c.2553G>C p.R851= | Silent (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- SERPINB6 | c.1179C>G p.S393= (on ENST00000612421 / NM_001271823.2; = p.S374= on NM_004568.6) | Silent (SNP) | VAF 28/387 reads (7%) | catalogued as rs768602128; called by muse, mutect2
- TMEM151B | c.882C>A p.P294= | Silent (SNP) | VAF 28/184 reads (15%) | called by muse, mutect2, varscan2
- TMEM236 | c.948A>T p.T316= | Silent (SNP) | VAF 65/642 reads (10%) | called by mutect2, varscan2
- ZMYND8 | c.2904G>A p.E968= (on ENST00000311275 / NM_001363741.2; = p.E942= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/322 reads (6%) | catalogued as COSV53696825; called by muse, mutect2
- ZNF516 | c.12C>T p.N4= | Silent (SNP) | VAF 28/251 reads (11%) | catalogued as rs754764602; called by muse, mutect2, varscan2
- AC116366.2 | c.-659_-655del | 5'UTR (DEL) | VAF 30/233 reads (13%) | called by mutect2, pindel, varscan2
- BLOC1S5-TXNDC5 | c.372+39434C>T | Intron (SNP) | VAF 54/574 reads (9%) | called by muse, mutect2
- CACNB4 | c.390+55T>G | Intron (SNP) | VAF 37/246 reads (15%) | called by muse, mutect2, varscan2
- CCHCR1 | c.-51-358T>C | Intron (SNP) | VAF 54/550 reads (10%) | called by muse, mutect2
- NME5 | c.129+27dup | Intron (INS) | VAF 18/140 reads (13%) | called by mutect2, varscan2
- PHF20 | c.1826-137del | Intron (DEL) | VAF 21/216 reads (10%) | called by mutect2, pindel, varscan2
- POMT2 | c.1725+16G>T | Intron (SNP) | VAF 52/431 reads (12%) | called by muse, varscan2
- RN7SL484P | chr15:99792697 G>A | 3'Flank (SNP) | VAF 24/255 reads (9%) | catalogued as rs1407716729; called by muse, mutect2, varscan2
- SLC27A4 | c.-6-857C>T | Intron (SNP) | VAF 32/246 reads (13%) | catalogued as rs551080094, COSV55960798, COSV55960909; called by muse, mutect2, varscan2
- ZNF528 | c.272-836C>G | Intron (SNP) | VAF 43/325 reads (13%) | catalogued as rs761426106; called by muse, mutect2, varscan2
- ZNF829 | c.-85+146A>C | Intron (SNP) | VAF 28/337 reads (8%) | called by muse, mutect2
